Surgical pathology report (de-identified scan), TCGA case TCGA-FY-A2QD, project TCGA-THCA (Thyroid Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-FY-A2QD-01A (Primary Tumor).

[page 1 of 2]
SPECIMEN INFORMATION

Accession #

Acct / Reg #

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

A. Parathyroid; excision:

Benign thyroid, no parathyroid identified.
Intraoperative consultation corroborated.

B. Thyroid; total thyroidectomy:

Tumor Characteristics:

1. Histologic type: Papillary thyroid carcinoma.
2. Tumor laterality: Left lobe.
3. Tumor focality: Multifocal (single dominant nodule with satellite microscopic nodule).
4. Size of largest focus: 0.6 cm as measured on slide B6.
5. Tumor capsule: Partially present.
6. Tumor capsular invasion: Present.
7. Extrathyroidal extension of tumor: Not identified.
8. Lymphovascular space invasion: Not identified.

Surgical Margin Status:

1. All surgical margins are free of tumor.

Lymph Node Status:

1. Total number of lymph nodes examined: Three (see specimen C).
2. Total number of lymph nodes containing metastatic carcinoma: Zero (0/3).

Other Findings:

1. Hashimoto's thyroiditis.
2. Follicular adenoma, 6.0 cm, right side.
3. pTNM stage: pT1N0.

C. Superior mid thyroid mass; excision:

Three lymph nodes with no metastatic carcinoma identified (0/3).

1CD-0-3

carcinoma, papillary, thyroid 8260/3
Site: thyroid, NOS C73.9

hw
9/3/11

Electronic Signature

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis:

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Parathyroid ? with frozen section.
- B. Total thyroid right side stitch.
- C. Superior mid thyroid mass.

SPECIMEN DATA

GROSS DESCRIPTION:

Specimen is received in three containers labeled:

- A. Container A is additionally labeled parathyroid ? and contains a 0.5 cm pink-tan rubbery soft tissue entirely submitted for frozen section, the residual entirely resubmitted for permanent section in cassette A labeled

[page 2 of 2]
B. Container B is additionally labeled total thyroid stitch right side and contains a 46.5 gram total thyroidectomy specimen comprised of right lobe (6.7 x 3.5 x 3.0 cm), left lobe (5.0 x 3.0 x 2.0 cm) and isthmus (1.5 x 0.7 x 0.5 cm). The capsule is purple-pink and shaggy with no parathyroid glands identified. The specimen is inked as follows: right side - blue and left side - black. Specimen is serially sectioned to reveal a 6.0 x 3.3 x 2.5 cm encapsulated pink-tan mass involving most of the right lobe and approaching to within 0.1 cm of the inked capsule. The remainder of the cut surface is beef red and glistening with focal areas of yellow-tan discoloration near the capsule. Representative sections are submitted in cassettes B1-12 labeled as follows: 1-5 - right lobe, 6-10 - left lobe, 11 & 12 - isthmus. Additionally, a yellow-green and blue cassette are submitted for Genomics research each labeled:

C. Container C is additionally labeled superior mid thyroid of mass and contains a 1.3 x 0.9 x 0.7 cm rubbery tan-pink soft tissue. Specimen is inked and bisected to reveal a beefy red glistening cut surface. The specimen is entirely submitted in cassette C labeled:

INTRA-OPERATIVE CONSULTATION:

FROZEN SECTION DIAGNOSIS A: Thyroid, no parathyroid pe

Source: NCI Genomic Data Commons file c7092e6d-2e73-4511-a471-f32bd90d4a98 (TCGA-FY-A2QD.D4447081-2054-46B6-B83F-C0D2DF8C4AA1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).